Somatic mutation profile of tumor specimen MP2PRT-PATXJS-TMP1-A (aliquot MP2PRT-PATXJS-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATXJS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,369 days).
Specimen MP2PRT-PATXJS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e7d6c31-5d50-4638-851a-3732fe9dafef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATXJS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATXJS-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5fb8d67-c8a0-4fc9-b3db-4ff24a92c44a

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, RNA 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX3 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 64/417 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs771356481, COSV62713176; called by muse, mutect2, varscan2
- ADAMTS7 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 142/651 reads (22%) | catalogued as rs528231699, COSV66305712; called by muse, mutect2, varscan2
- AXIN2 | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 227/814 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs730881401, COSV61061784; ClinVar: uncertain significance; called by mutect2, varscan2
- CCDC80 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 18/551 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1371538204, COSV52817068; called by muse, mutect2
- CFAP46 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 101/720 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs915496495; called by muse, mutect2, varscan2
- CNTN4 | c.2227G>A p.G743S | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs900278144; called by muse, mutect2, varscan2
- DMBT1 | c.7409G>A p.R2470H (on ENST00000338354 / NM_001377530.1; = p.R1713H on NM_004406.3) | Missense Mutation (SNP) | VAF 118/617 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57538376; called by muse, mutect2, varscan2
- GATA3 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 265/1167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771315353, COSV60515507, COSV60517246, COSV60518853; called by muse, mutect2, varscan2
- ZER1 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 109/889 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.123); catalogued as rs1192457302, COSV52568208; called by muse, mutect2, varscan2
- DYSF | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 99/421 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PRDX5 | c.376_377insGGAG p.L126Rfs*5 | Frame Shift Ins (INS) | VAF 120/515 reads (23%) | called by mutect2, pindel, varscan2
- ZSCAN5C | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 120/451 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- ZYG11A | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- BAG5 | c.1113C>T p.N371= | Silent (SNP) | VAF 57/318 reads (18%) | catalogued as rs749145244, COSV54570307; called by muse, mutect2, varscan2
- JAKMIP1 | c.51C>T p.D17= | Silent (SNP) | VAF 141/745 reads (19%) | catalogued as rs766389811, COSV51533505; called by muse, mutect2, varscan2
- KLHL29 | c.1662C>T p.N554= | Silent (SNP) | VAF 146/604 reads (24%) | catalogued as rs529955357, COSV99942963; called by muse, varscan2
- NUP205 | c.1758C>T p.S586= | Silent (SNP) | VAF 49/288 reads (17%) | called by muse, mutect2, varscan2
- RBM4B | c.306T>C p.G102= | Silent (SNP) | VAF 144/529 reads (27%) | called by muse, mutect2, varscan2
- TJP1 | c.4026G>A p.R1342= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as rs921272774; called by muse, mutect2, varscan2
- TRPA1 | c.1726C>T p.L576= | Silent (SNP) | VAF 72/352 reads (20%) | called by muse, mutect2, varscan2
- XIST | n.9176C>T | RNA (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2
- XIST | n.9175C>T | RNA (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2
